Somatic mutation profile of tumor specimen C3L-05387-54 (aliquot CPT0275090002) from CPTAC case C3L-05387, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.1 years (24,141 days).
Specimen C3L-05387-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c88b6d2b-0d0e-46ac-ada8-3a3c354f058c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05387-52 (Buccal Cell Normal), aliquot CPT0275080001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d033cf4-ce32-4d6d-b8a3-b59abf647e8a

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, 5'UTR 1, Frame Shift Ins 1, Silent 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IVL | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs745982628, COSV64216144; called by muse, varscan2
- KHDRBS2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1424208139, COSV55434666, COSV99832969; called by muse, mutect2, varscan2
- MUC16 | c.34604C>T p.T11535M | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.818); catalogued as rs111231164, COSV67472305; called by muse, mutect2, varscan2
- MYLK | c.4415C>T p.S1472F | Missense Mutation (SNP) | VAF 137/395 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs773996829, COSV60613019, COSV60615269; called by muse, mutect2, varscan2
- POLR1A | c.2395G>T p.V799L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV55697776, COSV99808556; called by muse, mutect2, varscan2
- TRIP6 | c.260dup p.L88Pfs*37 | Frame Shift Ins (INS) | VAF 49/131 reads (37%) | catalogued as rs774628656; called by mutect2, varscan2
- AMZ1 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CCDC87 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SAP130 | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CPXM2 | c.1830C>T p.Y610= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs75791971, COSV53855665; called by muse, mutect2, varscan2
- KIF26B | c.999+3264C>T | Intron (SNP) | VAF 36/276 reads (13%) | catalogued as rs1017464123, COSV68572324; called by muse, mutect2, varscan2
- OR10AB1P | n.827A>G | RNA (SNP) | VAF 103/270 reads (38%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159585 T>A | 5'Flank (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.-35C>G | 5'UTR (SNP) | VAF 108/278 reads (39%) | called by mutect2, varscan2
- WRAP53 | c.955+85G>A | Intron (SNP) | VAF 81/205 reads (40%) | called by muse, mutect2, varscan2
